Somatic mutation profile of tumor specimen 0DBW4E from CCDI case PBBKDM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,228 days).
Specimen 0DBW4E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b3bafd-c4da-476d-b686-f6a37c7d31f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBW3U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b061fde-94a8-4324-bd9f-14263b913d2e

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EML3 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs950352101; called by muse, mutect2, varscan2
- DEPDC4 | c.577A>T p.N193Y | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 47/1618 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 15/308 reads (5%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 54/1345 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 11/99 reads (11%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 33/211 reads (16%) | called by muse, varscan2
